Gene-level copy-number profile of tumor specimen TCGA-XF-AAMY-01A from TCGA case TCGA-XF-AAMY, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 78.1 years (28,509 days).
Specimen TCGA-XF-AAMY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.6024523f-82aa-47b4-9d2c-83ed01d2b338.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-AAMY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5ac1bd5d-8650-4519-8b30-2d9016af3938

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,363; copy number 2: 6,475; copy number 3: 25,720; copy number 4: 16,312; copy number 5: 4,683; copy number 6: 2,164; copy number 7: 1,141; copy number 8: 264; copy number 9: 92; copy number 10: 159; copy number 11: 3; copy number 12: 150; copy number 13: 125; copy number 15: 10; copy number 17: 57; copy number 20: 68; copy number 27: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-AAMY-01A-11D-A42D-01): tumor purity 0.61, ploidy 3.58, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,095 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,809,713–150,876,708, 1 gene, copy number 7 (within-gene range 4–7): ARNT.
- chr1:150,881,236–151,853,712, 67 genes, copy number 7 (broad region; genes not listed).
- chr3:12,004,388–12,434,356, 7 genes, copy number 8–11: SYN2, ACTG1P12, TIMP4, MTCO1P5, GSTM5P1, PPARG, AC091492.1.
- chr3:31,657,890–32,621,902, 22 genes, copy number 8 (within-gene range 5–8): OSBPL10, OSBPL10-AS1, ZNF587P1, ZNF860, RPL21P40, AC094019.1, Y_RNA, NIFKP7, GPD1L, AC094019.2, RPSAP11, AC097639.1, CMTM8, AC097639.2, KRT18P15, CMTM7, CMTM6, MIR548AY, AC104306.1, DYNC1LI1, AC104306.2, IGBP1P3.
- chr3:52,694,488–53,347,586, 26 genes, copy number 7 (within-gene range 5–7): GLT8D1, SPCS1, NEK4, AC104446.2, AC006254.2, AC006254.3, ITIH1, ITIH3, ITIH4, AC006254.1, ITIH4-AS1, MUSTN1, STIMATE-MUSTN1, STIMATE, MIR8064, AC099667.1, SFMBT1, AC096887.1, AC096887.2, SERBP1P3, RFT1, PRKCD, AC097015.1, TKT, DCP1A, Y_RNA.
- chr6:19,323,428–19,839,080, 1 gene, copy number 17 (within-gene range 2–17): LNC-LBCS.
- chr6:19,612,755–28,534,955, 268 genes, copy number 8–17 (broad region; genes not listed).
- chr8:51,319,577–51,809,445, 1 gene, copy number 12 (within-gene range 5–12): PXDNL.
- chr8:51,721,670–54,192,035, 43 genes, copy number 12: BTF3P1, AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3, ST18, AC021915.2, AC021915.1, AC103831.1, RPL34P17, ALKAL1, RB1CC1, AC113139.1, NPBWR1, AC009800.1, AC009646.1, AC009646.2, OPRK1, AC131902.1, AC022034.3, AC131902.2, AC022034.1, AC022034.4, AC022034.2, MAPK6P1, AC103778.1, ATP6V1H, RGS20, AC113194.1, RPS27AP13, RNU6-1331P, TCEA1, AC100821.1, AC100821.2, LYPLA1, TDGF1P5, Metazoa_SRP, MRPL15, RNU6ATAC32P, AC060764.1.
- chr8:73,420,369–81,759,515, 136 genes, copy number 10 (within-gene range 5–10) (broad region; genes not listed).
- chr8:82,862,779–83,408,900, 6 genes, copy number 8: AC105031.2, AC105031.1, AC090095.1, AC090132.1, AC090132.2, LINC01419.
- chr8:88,326,836–88,887,573, 1 gene, copy number 12 (within-gene range 5–12): AC090578.1.
- chr8:88,808,318–91,398,155, 32 genes, copy number 8–13 (within-gene range 5–13): AC090578.2, AC090578.3, RPSAP74, KRT8P4, AF117829.1, RIPK2, COX6B1P6, AF117829.2, RNU6-925P, OSGIN2, NBN, DECR1, CALB1, AC004083.1, LINC00534, RNA5SP273, LINC01030, TMEM64, AC106038.1, AC106038.2, NECAB1, AC103770.1, C8orf88, PIP4P2, AC087439.1, AC087439.2, OTUD6B-AS1, OTUD6B, LRRC69, CPP, MIR4661, SLC26A7.
- chr8:95,599,114–103,501,895, 179 genes, copy number 8–27 (broad region; genes not listed).
- chr8:103,559,099–103,568,978, 2 genes, copy number 13: PTMAP15, AC007751.1.
- chr8:113,950,886–117,318,701, 23 genes, copy number 7–9: Y_RNA, AC064802.1, AC025881.1, CARS1P2, TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1.
- chr12:56,987,734–57,846,729, 60 genes, copy number 12 (within-gene range 4–12): AC026120.3, GPR182, ZBTB39, TAC3, MYO1A, NEMP1, NAB2, STAT6, LRP1, LRP1-AS, MIR1228, NXPH4, AC137834.2, SHMT2, NDUFA4L2, STAC3, AC137834.1, R3HDM2, RNU6-879P, AC126614.1, INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2.
- chr12:65,589,111–67,069,162, 24 genes, copy number 7–10 (within-gene range 3–15): LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB, GRIP1.
- chr12:66,950,754–70,354,993, 78 genes, copy number 15–20 (broad region; genes not listed).
- chr16:25,111,731–26,729,126, 21 genes, copy number 8 (within-gene range 3–8): LCMT1, LCMT1-AS2, RN7SL557P, AQP8, ZKSCAN2, AC008741.1, ZKSCAN2-DT, LINC02191, CYCSP39, HS3ST4, AC093516.1, AC093524.1, MIR548W, RNA5SP405, HMGN2P3, HSPE1P16, AC009158.1, AC130464.1, AC002331.1, LINC02195, AC009035.1.
- chr16:46,469,341–48,498,601, 55 genes, copy number 8: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2, DNAJA2, AC018845.3, AC018845.1, AC018845.2, NETO2, ITFG1-AS1, RPL23AP72, ITFG1, AC007494.2, AC007494.3, AC007494.1, AC007533.1, Y_RNA, 5S_rRNA, PHKB, RNA5SP425, AC007599.2, AC007599.1, EIF4BP5, NDUFA5P11, LINC02133, AC141846.1, LINC02192, LINC02134, AC096996.3, AC096996.1, ABCC12, AC096996.2, ABCC11, LONP2, UBA52P8, AC023818.1, SIAH1, Metazoa_SRP, AC026470.3, AC026470.1, MOCS1P1.
- chr16:50,152,911–90,222,851, 1,042 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
